Somatic mutation profile of tumor specimen TCGA-ER-A19P-06A (aliquot TCGA-ER-A19P-06A-11D-A196-08) from TCGA case TCGA-ER-A19P, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 58.6 years (21,386 days).
Specimen TCGA-ER-A19P-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41d2c21f-9cf0-433b-a4ad-95d6c2b181e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A19P-10A (Blood Derived Normal), aliquot TCGA-ER-A19P-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69d72b56-acc3-455d-818a-acaac4f0e357

The open-access MAF lists 194 somatic variants for this specimen: 136 protein-altering or splice-affecting, 53 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 119, Silent 53, Nonsense Mutation 12, Intron 2, RNA 2, Frame Shift Del 2, Splice Region 2, 5'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AADACL4 | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV66107160; called by muse, mutect2
- ABCC9 | c.4222G>A p.D1408N | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53984869; called by muse, varscan2
- ABLIM2 | c.1405G>A p.D469N (on ENST00000341937 / NM_001130084.2; = p.D418N on NM_032432.5) | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV56411246; called by muse, mutect2, varscan2
- ACSM2B | c.894G>A p.K298= | Splice Region (SNP) | VAF 14/110 reads (13%) | catalogued as COSV61659854; called by muse, mutect2, varscan2
- ADAMTS16 | c.762A>C p.K254N | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV99942861; called by muse, mutect2, varscan2
- ADAMTS6 | c.1573C>T p.P525S | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66860327, COSV66864284; called by muse, varscan2
- ALPK2 | c.3155C>T p.P1052L | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.225); catalogued as rs769727633, COSV64492923; called by muse, mutect2, varscan2
- AMBRA1 | c.1783G>C p.E595Q (on ENST00000458649 / NM_001367468.1; = p.E505Q on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.35); catalogued as COSV54047898, COSV54062127; called by muse, mutect2
- AMOT | c.1613C>T p.S538L (on ENST00000371959 / NM_001113490.1; = p.S129L on NM_133265.3) | Missense Mutation (SNP) | VAF 54/280 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs768294379, COSV59067879; called by muse, varscan2
- AOC1 | c.992C>T p.S331F | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs753490000, COSV62869643; called by mutect2, varscan2
- APOB | c.4115C>T p.S1372F | Missense Mutation (SNP) | VAF 19/290 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs930883549, COSV51951193; called by muse, mutect2
- ASB1 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as rs750406228, COSV52828277; called by muse, mutect2, varscan2
- BAZ1A | c.953A>G p.K318R | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV62412084; called by muse, mutect2, varscan2
- BRSK2 | c.1181C>A p.P394Q | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100373140, COSV57539636; called by mutect2, varscan2
- C12orf40 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.716); catalogued as COSV61132265; called by muse, varscan2
- CACNA1D | c.2120G>A p.W707* (on ENST00000350061 / NM_001128840.3; = p.W727* on NM_000720.4) | Nonsense Mutation (SNP) | VAF 21/182 reads (12%) | catalogued as COSV55463867; called by muse, mutect2, varscan2
- CATSPER4 | c.1088G>A p.G363E | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.881); catalogued as rs1420151559, COSV58794617; called by muse, varscan2
- CCDC146 | c.2248G>A p.E750K | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs267601574; called by mutect2, varscan2
- CCDC7 | c.2689G>A p.E897K | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.99); catalogued as rs1485046035, COSV56551376; called by mutect2, varscan2
- CDC23 | c.1255C>A p.L419I | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV67510048; called by muse, varscan2
- CDH9 | c.1543G>A p.D515N | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1299427249, COSV99142444; called by muse, varscan2
- CLMP | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.637); catalogued as COSV71650584; called by muse, mutect2, varscan2
- CNGB1 | c.3350G>A p.G1117E | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.197); catalogued as COSV51906685; called by muse, mutect2, varscan2
- CNGB3 | c.1625C>T p.S542F | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60697853; called by muse, mutect2, varscan2
- CNGB3 | c.901C>T p.Q301* | Nonsense Mutation (SNP) | VAF 14/95 reads (15%) | catalogued as rs868249629, COSV60697861; called by mutect2, varscan2
- COL6A3 | c.5357T>C p.V1786A | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as rs1277676887, COSV55108050; called by muse, mutect2
- COPG2 | c.398A>C p.D133A | Missense Mutation (SNP) | VAF 40/296 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58406863; called by muse, mutect2, varscan2
- CR2 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV65509519; called by muse, mutect2, varscan2
- CRHR2 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1271899323, COSV59267761; called by muse, mutect2, varscan2
- CTNNA3 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.89); PolyPhen probably damaging (0.989); catalogued as COSV57721976; called by muse, varscan2
- CUL2 | c.367C>T p.L123F | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV101039293; called by muse, mutect2, varscan2
- CUL4B | c.1468C>T p.L490F | Missense Mutation (SNP) | VAF 44/305 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs267606335, COSV60690965; called by muse, mutect2, varscan2
- DCLRE1A | c.2387G>A p.G796D | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63749664; called by muse, varscan2
- DCUN1D4 | c.407C>A p.P136Q | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV58124760, COSV58125091; called by mutect2, varscan2
- DDI2 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 42/308 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); catalogued as COSV60781392; called by muse, varscan2
- DNMT1 | c.3973C>T p.P1325S | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV61576450; called by muse, mutect2, varscan2
- DSG3 | c.1675C>T p.P559S | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV57125275; called by muse, varscan2
- DUOX1 | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as COSV50994069; called by mutect2, varscan2
- FAM227B | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV54818849, COSV54819002; called by muse, varscan2
- FKBP6 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs782429549, COSV52722903; called by muse, mutect2, varscan2
- GABRB2 | c.417G>A p.M139I | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV50942012; called by mutect2, varscan2
- GAS2L2 | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as rs370992265; called by mutect2, varscan2
- GKAP1 | c.983C>T p.S328L | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV64487517; called by mutect2, varscan2
- GREM1 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV100277973, COSV55715881; called by mutect2, varscan2
- GRHL3 | c.440C>T p.P147L (on ENST00000350501 / NM_198174.3; = p.P152L on NM_021180.3) | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV52570717; called by muse, varscan2
- GRIK3 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768224744, COSV66135545; called by muse, mutect2, varscan2
- GRIN3A | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV62453473; called by muse, varscan2
- GTF3C2 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53128676; called by muse, varscan2
- HCK | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs778012775, COSV52946920; called by muse, varscan2
- HECTD1 | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV67948993; called by muse, varscan2
- HIVEP1 | c.1759C>T p.L587F | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); catalogued as COSV65104863; called by muse, mutect2, varscan2
- HMCN1 | c.16598C>T p.A5533V | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54938779; called by muse, varscan2
- HTR3B | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.168); catalogued as rs917472689, COSV52747519; called by muse, mutect2, varscan2
- IGHV3-7 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 26/228 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); catalogued as rs781886233; called by muse, mutect2, varscan2
- IL15RA | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.042); catalogued as COSV66093178; called by muse, mutect2, varscan2
- INSR | c.1543A>T p.R515* | Nonsense Mutation (SNP) | VAF 54/466 reads (12%) | catalogued as COSV57172759; called by muse, mutect2, varscan2
- KANK4 | c.1964G>A p.G655E | Missense Mutation (SNP) | VAF 13/167 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.168); catalogued as rs1190716141, COSV100587688; called by muse, mutect2
- KANSL1L | c.697A>G p.I233V | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV55996952; called by muse, mutect2
- KCTD8 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV63584894; called by mutect2, varscan2
- KIF4B | c.905G>A p.G302E | Missense Mutation (SNP) | VAF 66/238 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV70531201; called by muse, mutect2, varscan2
- KLHL15 | c.1262G>A p.G421E | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV60140850, COSV60141937; called by muse, mutect2, varscan2
- LMOD1 | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 32/244 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); catalogued as COSV66173875; called by muse, varscan2
- LONRF2 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV66540201; called by muse, varscan2
- LPA | c.1135C>T p.R379* | Nonsense Mutation (SNP) | VAF 11/59 reads (19%) | catalogued as rs1191914217; called by mutect2, varscan2
- MAGEA12 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.825); catalogued as COSV63295433; called by muse, mutect2, varscan2
- MCM5 | c.709C>A p.P237T | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53348113; called by mutect2, varscan2
- ME1 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.802); catalogued as COSV63842398; called by muse, varscan2
- MUC16 | c.42310G>A p.G14104R | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.797); catalogued as COSV66696165; called by muse, mutect2, varscan2
- MUC16 | c.691G>T p.G231W | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.906); catalogued as COSV67491423; called by mutect2, varscan2
- MYCBP2 | c.1669C>T p.L557F (on ENST00000357337; = p.L595F on NM_015057.5) | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62038014; called by muse, mutect2
- MYF5 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.175); catalogued as COSV57355691; called by muse, varscan2
- MYH8 | c.851G>A p.R284K | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV67962603, COSV67971974; called by muse, mutect2, varscan2
- NES | c.1619C>T p.P540L | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); catalogued as COSV63962832; called by muse, mutect2
- NLRP13 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs866889624, COSV61620245; called by muse, mutect2, varscan2
- NLRP8 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV52593385; called by muse, mutect2
- NUP153 | c.1472C>T p.S491F | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.067); catalogued as COSV100020807; called by muse, mutect2
- OR3A1 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as rs749032687, COSV60163021; called by mutect2, varscan2
- OR4C11 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as COSV56354911; called by muse, varscan2
- OR5T3 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs149435695, COSV57379915; called by muse, mutect2, varscan2
- OVCH1 | c.455G>A p.G152E | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV58967901; called by muse, varscan2
- PADI3 | c.1649G>A p.W550* | Nonsense Mutation (SNP) | VAF 8/86 reads (9%) | catalogued as rs895929989, COSV64935349; called by muse, mutect2
- PCDH11X | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100014971; called by muse, mutect2
- PCDHA1 | c.1118C>T p.T373I | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.472); catalogued as COSV65376814; called by muse, mutect2, varscan2
- PCDHGA2 | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.021); catalogued as COSV54025486; called by muse, mutect2
- PDE7B | c.872T>C p.L291S | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57508203; called by muse, mutect2, varscan2
- PDHA1 | c.641G>A p.W214* | Nonsense Mutation (SNP) | VAF 33/263 reads (13%) | catalogued as COSV58837954; called by muse, mutect2, varscan2
- PKD2L2 | c.1737G>A p.M579I | Missense Mutation (SNP) | VAF 37/204 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV50373441; called by muse, mutect2, varscan2
- PLEKHS1 | c.334C>A p.H112N (on ENST00000369310 / NM_182601.1; = p.H118N on NM_024889.5) | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as COSV63056732; called by mutect2, varscan2
- POP1 | c.1909C>T p.R637* | Nonsense Mutation (SNP) | VAF 16/136 reads (12%) | catalogued as rs750817485, COSV62892696; called by mutect2, varscan2
- PRRG3 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.92); catalogued as rs950659306, COSV64851468; called by muse, mutect2, varscan2
- RFX4 | c.1252G>A p.G418R (on ENST00000392842 / NM_213594.3; = p.G324R on NM_032491.6) | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.996); catalogued as COSV57581070; called by muse, varscan2
- RIOK1 | c.197A>T p.D66V | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV53573487; called by muse, varscan2
- SCIN | c.2117G>A p.W706* (on ENST00000297029 / NM_001112706.3; = p.W459* on NM_033128.3) | Nonsense Mutation (SNP) | VAF 27/152 reads (18%) | catalogued as COSV99765284; called by mutect2, varscan2
- SCIN | c.2118G>A p.W706* (on ENST00000297029 / NM_001112706.3; = p.W459* on NM_033128.3) | Nonsense Mutation (SNP) | VAF 29/162 reads (18%) | catalogued as COSV51689106, COSV51693585; called by muse, mutect2, varscan2
- SDCBP2 | c.553C>T p.R185W (on ENST00000339987 / NM_001199784.1; = p.R100W on NM_015685.5) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1383253202, COSV60590514; called by mutect2, varscan2
- SLC13A2 | c.1249A>T p.M417L | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.03); catalogued as COSV58998405; called by muse, varscan2
- SLC15A1 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64712953; called by muse, mutect2, varscan2
- SLC44A5 | c.1193C>T p.S398L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs867895969, COSV63757791, COSV63758383; called by muse, varscan2
- SLC7A2 | c.833G>A p.G278D (on ENST00000494857 / NM_001370338.1; = p.G318D on NM_003046.6) | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50271681; called by muse, varscan2
- SLC9C2 | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as rs867737971, COSV62945191; called by mutect2, varscan2
- SLFN5 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 31/232 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.679); catalogued as rs764171232, COSV55481002; called by muse, mutect2, varscan2
- SNAI2 | c.715A>G p.K239E | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV50079173; called by muse, varscan2
- SPOCD1 | c.2970G>T p.W990C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.533); catalogued as COSV99930264, COSV99930339; called by mutect2, varscan2
- SSTR1 | c.431G>A p.S144N | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57457496; called by muse, mutect2, varscan2
- SYNE1 | c.17921C>T p.S5974F (on ENST00000367255 / NM_182961.4; = p.S5903F on NM_033071.3) | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55093071; called by muse, mutect2, varscan2
- TBRG1 | c.1094C>T p.S365F | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.259); catalogued as COSV52516744; called by mutect2, varscan2
- TDRD5 | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV54249862; called by muse, varscan2
- TET1 | c.4906C>A p.Q1636K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.314); catalogued as COSV65389272; called by mutect2, varscan2
- TEX45 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV100861826; called by muse, mutect2
- TGIF2LX | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.014); catalogued as COSV52214152, COSV52215142; called by muse, mutect2, varscan2
- TMTC4 | c.322C>T p.H108Y (on ENST00000376234 / NM_001350577.2; = p.H127Y on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60893492; called by mutect2, varscan2
- TNIK | c.1490G>A p.R497K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV52685490; called by mutect2, varscan2
- TOP2B | c.3413C>T p.P1138L (on ENST00000264331 / NM_001330700.2; = p.P1133L on NM_001068.3) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV51976914; called by muse, varscan2
- TRIML1 | c.1337C>T p.S446F | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as rs1316000776, COSV60194018, COSV60196036; called by muse, mutect2, varscan2
- TTN | c.6890G>A p.G2297E (on ENST00000591111; = p.G2251E on NM_003319.4) | Missense Mutation (SNP) | VAF 10/96 reads (10%) | PolyPhen probably damaging (1); catalogued as COSV59874453; called by muse, mutect2, varscan2
- TXNDC12 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65406097; called by muse, varscan2
- UGGT1 | c.1549G>A p.A517T | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as COSV52136354; called by muse, mutect2, varscan2
- UNC13C | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as COSV52846044; called by muse, mutect2, varscan2
- USPL1 | c.2918C>G p.A973G | Missense Mutation (SNP) | VAF 25/213 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55002270; called by muse, mutect2, varscan2
- VPS35 | c.871C>G p.Q291E | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV54481084; called by muse, mutect2
- WBP1 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51971545; called by muse, mutect2, varscan2
- WDR44 | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV54168604; called by mutect2, varscan2
- XKR9 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as rs1435305195, COSV68772539; called by muse, varscan2
- YWHAB | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV62304822; called by muse, varscan2
- ZNF114 | c.706C>T p.L236F | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV59945245; called by muse, mutect2, varscan2
- ZNF254 | c.1384T>C p.Y462H | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100741769; called by muse, mutect2, varscan2
- ZNF362 | c.1121G>A p.S374N | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.95); catalogued as COSV65031934; called by muse, varscan2
- ZNF429 | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 24/166 reads (14%) | catalogued as rs764232949, COSV61918920; called by muse, mutect2, varscan2
- ZNF474 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1405305062, COSV56947538; called by muse, varscan2
- ZNF630 | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV99332580; called by muse, mutect2
- ADGRL3 | c.1214_1217del p.N405Rfs*48 (on ENST00000506720 / NM_001322402.2; = p.N337Rfs*48 on NM_015236.6) | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by pindel, varscan2
- DDX39B | c.615C>A p.L205= | Splice Region (SNP) | VAF 14/206 reads (7%) | called by muse, mutect2
- GLT8D2 | c.835G>T p.G279W | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by mutect2, varscan2
- IRF2BP1 | c.1300_1301del p.G434Pfs*145 | Frame Shift Del (DEL) | VAF 5/50 reads (10%) | called by mutect2, pindel
- MMAA | c.841G>T p.E281* | Nonsense Mutation (SNP) | VAF 13/203 reads (6%) | called by muse, mutect2
- PRAMEF19 | c.448T>C p.F150L | Missense Mutation (SNP) | VAF 28/381 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.061); called by muse, mutect2
- CHGB | c.1728C>T p.F576= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV66761675; called by muse, varscan2
- CMYA5 | c.8929T>C p.L2977= | Silent (SNP) | VAF 22/101 reads (22%) | catalogued as COSV71409300; called by muse, mutect2, varscan2
- COPS2 | c.1162T>C p.L388= | Silent (SNP) | VAF 42/304 reads (14%) | catalogued as COSV54647382; called by muse, mutect2, varscan2
- CPE | c.546C>T p.A182= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as rs1297353438, COSV68582475; called by muse, varscan2
- CTBP2 | c.1164G>A p.P388= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs756901110, COSV58337783; called by mutect2, varscan2
- CUL2 | c.366C>T p.D122= | Silent (SNP) | VAF 27/153 reads (18%) | catalogued as rs751929559, COSV101039294; called by muse, mutect2, varscan2
- DENND2A | c.2569C>T p.L857= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as COSV52058439; called by muse, varscan2
- DIAPH1 | c.2436C>T p.F812= | Silent (SNP) | VAF 36/183 reads (20%) | catalogued as rs185113837; called by mutect2, varscan2
- DIO1 | c.351G>A p.L117= | Silent (SNP) | VAF 18/258 reads (7%) | catalogued as COSV59518841; called by muse, mutect2
- DISP3 | c.2481C>T p.F827= | Silent (SNP) | VAF 17/168 reads (10%) | catalogued as COSV53824346; called by muse, mutect2, varscan2
- DPY19L2 | c.1860G>A p.Q620= | Silent (SNP) | VAF 12/113 reads (11%) | catalogued as COSV61046070; called by muse, varscan2
- DSCAM | c.123G>A p.G41= | Silent (SNP) | VAF 22/136 reads (16%) | catalogued as COSV68653505; called by muse, varscan2
- FBN3 | c.5997C>T p.G1999= | Silent (SNP) | VAF 19/98 reads (19%) | catalogued as COSV54472086; called by muse, mutect2, varscan2
- HCAR2 | c.420C>T p.S140= | Silent (SNP) | VAF 29/124 reads (23%) | catalogued as COSV61025760; called by muse, mutect2, varscan2
- HECW2 | c.2694C>T p.F898= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV53673447; called by muse, mutect2, varscan2
- HINFP | c.252C>T p.R84= | Silent (SNP) | VAF 17/204 reads (8%) | catalogued as COSV63432698; called by muse, mutect2
- HNF1A | c.147C>T p.S49= | Silent (SNP) | VAF 14/247 reads (6%) | catalogued as rs1184439814, COSV57466733; called by muse, mutect2
- IGHV1-18 | c.249C>T p.L83= | Silent (SNP) | VAF 18/155 reads (12%) | catalogued as rs782171300; called by muse, varscan2
- KANK4 | c.1914G>T p.S638= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as COSV62989202; called by muse, mutect2
- KCNH5 | c.1650T>G p.A550= | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as COSV59776575; called by muse, varscan2
- KRTAP13-2 | c.339A>T p.G113= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as COSV67762301; called by muse, mutect2, varscan2
- LRFN2 | c.312C>T p.S104= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as COSV57834167; called by muse, varscan2
- MAN2C1 | c.1545C>T p.F515= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as COSV51242888; called by muse, mutect2, varscan2
- MIEF1 | c.159G>T p.A53= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as COSV57480630; called by muse, varscan2
- MUC16 | c.10617C>T p.S3539= | Silent (SNP) | VAF 17/134 reads (13%) | catalogued as COSV67469574; called by muse, mutect2, varscan2
- MXRA5 | c.2376G>A p.G792= | Silent (SNP) | VAF 12/152 reads (8%) | catalogued as COSV54224878; called by muse, mutect2
- NCF2 | c.1407G>A p.E469= | Silent (SNP) | VAF 60/239 reads (25%) | catalogued as COSV62316699; called by muse, varscan2
- NPSR1 | c.1065G>A p.E355= | Silent (SNP) | VAF 17/180 reads (9%) | catalogued as COSV62207262; called by muse, mutect2
- OR10A2 | c.207G>T p.L69= | Silent (SNP) | VAF 16/144 reads (11%) | catalogued as COSV56300053, COSV56300435; called by mutect2, varscan2
- OR2T34 | c.162C>T p.I54= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as rs1443186990, COSV100170540; called by muse, mutect2, varscan2
- OR51B6 | c.306C>T p.I102= | Silent (SNP) | VAF 16/108 reads (15%) | catalogued as COSV66512399; called by muse, varscan2
- OR5P3 | c.186C>T p.F62= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as COSV60429278; called by muse, mutect2, varscan2
- PAQR3 | c.117C>T p.S39= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as COSV55011829; called by muse, varscan2
- PCDH18 | c.3153G>A p.Q1051= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV100787242, COSV61271896; called by muse, mutect2, varscan2
- PCDHA5 | c.915G>A p.G305= | Silent (SNP) | VAF 17/154 reads (11%) | catalogued as COSV65357494; called by muse, mutect2, varscan2
- PCDHB3 | c.270G>A p.L90= | Silent (SNP) | VAF 18/187 reads (10%) | catalogued as COSV50629570; called by muse, mutect2
- PCDHGA1 | c.2127C>T p.I709= | Silent (SNP) | VAF 34/188 reads (18%) | catalogued as rs750940303, COSV65296512, COSV65296741; called by muse, varscan2
- PDIA3 | c.393G>A p.Q131= | Silent (SNP) | VAF 52/272 reads (19%) | catalogued as COSV55858214; called by muse, mutect2, varscan2
- PSMC6 | c.627C>T p.F209= (on ENST00000612399; = p.F195= on NM_002806.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/191 reads (13%) | catalogued as COSV71629287; called by muse, mutect2, varscan2
- PTPRB | c.3300C>T p.H1100= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV99718865; called by mutect2, varscan2
- RHOU | c.472C>T p.L158= | Silent (SNP) | VAF 28/207 reads (14%) | catalogued as COSV64209092; called by muse, mutect2, varscan2
- RNF111 | c.198C>T p.H66= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV100789187; called by muse, mutect2, varscan2
- SBK1 | c.288G>A p.R96= | Silent (SNP) | VAF 33/185 reads (18%) | catalogued as COSV59398869; called by muse, mutect2, varscan2
- SLC25A52 | c.522G>A p.L174= (on ENST00000672005; = p.L164= on NM_001034172.4) | Silent (SNP) | VAF 30/226 reads (13%) | catalogued as COSV52501416; called by mutect2, varscan2
- SSX7 | c.126C>T p.S42= | Silent (SNP) | VAF 34/275 reads (12%) | catalogued as rs375280413, COSV53340775; called by muse, mutect2, varscan2
- TDRD6 | c.6072G>A p.L2024= | Silent (SNP) | VAF 34/178 reads (19%) | catalogued as COSV60178418; called by mutect2, varscan2
- TJP3 | c.1317G>A p.R439= | Silent (SNP) | VAF 21/179 reads (12%) | catalogued as COSV53665484; called by muse, mutect2, varscan2
- TNR | c.246G>A p.G82= | Silent (SNP) | VAF 15/136 reads (11%) | catalogued as COSV54911778; called by mutect2, varscan2
- UBA1 | c.2925C>T p.F975= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as COSV60115329; called by muse, mutect2, varscan2
- UBR4 | c.13506C>T p.R4502= | Silent (SNP) | VAF 15/151 reads (10%) | catalogued as COSV64398720; called by muse, mutect2, varscan2
- ULK1 | c.432C>T p.I144= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV58859785; called by muse, mutect2, varscan2
- WBP11 | c.163C>A p.R55= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV53764669; called by mutect2, varscan2
- ZNF254 | c.1383C>T p.P461= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV100741767; called by muse, mutect2, varscan2
- MIR1197 | n.5C>T | RNA (SNP) | VAF 9/71 reads (13%) | called by muse, varscan2
- NFYC | c.387+1124C>A | Intron (SNP) | VAF 14/124 reads (11%) | catalogued as COSV100438718, COSV58127387; called by muse, mutect2
- NOP56 | c.1010+90C>T | Intron (SNP) | VAF 10/70 reads (14%) | catalogued as rs775814004, COSV100250327; called by muse, mutect2
- OR2W5 | n.798G>A | RNA (SNP) | VAF 23/106 reads (22%) | catalogued as rs747421516; called by mutect2, varscan2
- TIFAB | c.-2C>T | 5'UTR (SNP) | VAF 16/74 reads (22%) | catalogued as COSV101538276; called by mutect2, varscan2
